Somatic mutation profile of tumor specimen TARGET-10-PASTXU-09A (aliquot TARGET-10-PASTXU-09A-01D) from TARGET case TARGET-10-PASTXU, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,711 days).
Specimen TARGET-10-PASTXU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8e476d8-569e-4770-97a5-de6be1b4fd8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASTXU-10A (Blood Derived Normal), aliquot TARGET-10-PASTXU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccb3117a-921c-4cb6-9298-fdd62fe1e84b

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 3, Intron 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV63416505; called by muse, mutect2
- ADGRB2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1339836779, COSV57078850, COSV99925645; called by muse, mutect2, varscan2
- CAD | c.2420A>C p.D807A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV53031797; called by muse, mutect2, varscan2
- FREM2 | c.5946C>A p.S1982R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as COSV54854835; called by muse, mutect2
- LETM1 | c.240_241insGGCTA p.R81Gfs*4 | Frame Shift Ins (INS) | VAF 68/176 reads (39%) | catalogued as COSV57104432; called by mutect2, pindel, varscan2
- NFE2L1 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | catalogued as rs1455746975, COSV62583795; called by muse, mutect2, varscan2
- NOTCH1 | c.7535C>T p.P2512L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160184715, COSV53028152; called by muse, mutect2, varscan2
- PHF6 | c.676G>A p.G226R (on ENST00000332070 / NM_032458.3; = p.G227R on NM_032335.3) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59706563; called by muse, mutect2, varscan2
- RGL1 | c.1980C>A p.N660K (on ENST00000360851 / NM_001297672.2; = p.N695K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100486124, COSV58996291; called by muse, mutect2, varscan2
- BCL11A | c.1378G>T p.E460* (on ENST00000335712 / NM_001365609.1; = p.E494* on NM_018014.4) | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- GABRB1 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- HOOK2 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.191); called by muse, mutect2
- MATN1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- MPDZ | c.5635G>T p.G1879* (on ENST00000319217 / NM_001330637.2; = p.G1850* on NM_003829.5) | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- NOTCH1 | c.4845_4857delinsT p.M1615_Y1619delinsI | In Frame Del (DEL) | VAF 35/110 reads (32%) | called by pindel, varscan2*
- NPAT | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.124); called by muse, mutect2
- OR51I1 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SNW1 | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- ANKRD55 | c.1326G>T p.L442= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- CSMD1 | c.2982C>T p.S994= (on ENST00000520002; = p.S993= on NM_033225.6) | Silent (SNP) | VAF 61/131 reads (47%) | catalogued as rs372606827; called by muse, mutect2, varscan2
- NRG1 | c.222C>A p.A74= (on ENST00000523534; = p.A221= on NM_013962.2) | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- PCDHB7 | c.1030C>A p.R344= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs566132808, COSV50804900; called by muse, mutect2
- WDR59 | c.2176C>A p.R726= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100049278; called by muse, mutect2, varscan2
- KIAA1958 | c.1172-26914C>A | Intron (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- SHOC2 | c.-235+17227C>T | Intron (SNP) | VAF 13/290 reads (4%) | catalogued as rs985512797; called by muse, mutect2
